Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9F7, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9F7-01A (Primary Tumor).

ICD-0.3
Melanoma, spindle cell &
epithelioid mixed 8710/3
Site: Choroid C69.3
QJ 2/16/14

Enucleation of the right eye

Macroscopy

The eyeball measures 28 by 25 mm and the optic nerve 11 mm. Samples have been made for cryo preservation. The specimen has been then included entirely.

Microscopy

The eyeball is occupied by a tumor proliferation morphologic features of which are those of a choroidal melanoma containing mostly fusiform cells (90%) and rarely epithelioid cells (10%). The lesion is loaded with melanin pigment. The mitotic index is low with 5 mitosis out of 10 high 400 magnification fields. The lesion infiltrates the internal third of the sclera, there is no extrascleral extension. The tumor proliferation infiltrates the intraocular emergence of the optic nerve but the optic foramen, the post laminar section, the cut end and the meningeal sheaths are free of tumor. The iris, the ciliary body and the anterior chamber are free of tumor.

Conclusion

Choroidal melanoma with mostly fusiform cells

Size of the lesion: 10mm

Low mitotic activity

The tumor proliferation infiltrates the intraocular emergence of the optic nerve but the optic foramen, the post laminar section, the cut end and the meningeal sheaths are free of tumor.

The iris, the ciliary body and the anterior chamber are free of tumor.

Local Malignancy History		
Metastatic/Synchronous Primary		

Source: NCI Genomic Data Commons file a7a92514-eb92-4db5-9972-9cfa86d8e2c4 (TCGA-V4-A9F7.39C2720B-D889-4D48-81EF-6DBC0D8A512C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).